Somatic mutation profile of tumor specimen TCGA-AH-6644-01A (aliquot TCGA-AH-6644-01A-21D-1826-10) from TCGA case TCGA-AH-6644, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 73.6 years (26,892 days).
Specimen TCGA-AH-6644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 498ec54b-5ad7-4111-a2a2-e24094faa0b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AH-6644-10A (Blood Derived Normal), aliquot TCGA-AH-6644-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cc08fc9-e211-42a2-bd3c-1e36dd18d550

The open-access MAF lists 115 somatic variants for this specimen: 81 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 28, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, 3'UTR 2, Intron 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 62/77 reads (81%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 70/178 reads (39%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs144434331, COSV54062853, COSV54063030; ClinVar: not provided; called by muse, mutect2, varscan2
- KAT8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 43/109 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896480; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/146 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5432G>A p.R1811Q | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs587784149, COSV61778115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 57/250 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13975G>A p.V4659M | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs369296047, COSV68951320; called by muse, mutect2, varscan2
- ABL1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs369393102; called by muse, mutect2, varscan2
- ASH1L | c.2548C>G p.P850A | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); catalogued as COSV100853302; called by muse, mutect2, varscan2
- ATP5F1D | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53066486; called by muse, mutect2, varscan2
- BTN3A3 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs144256388; called by muse, mutect2, varscan2
- CARD9 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs147340708; ClinVar: uncertain significance; called by muse, mutect2
- CCDC180 | c.4697G>A p.R1566H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs186799713; called by muse, mutect2, varscan2
- CDH9 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50305218; called by muse, mutect2, varscan2
- CHD5 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.441); catalogued as rs761147748, COSV52407127; called by muse, mutect2, varscan2
- CLEC4D | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV55229382; called by muse, mutect2, varscan2
- CPB1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142211299; called by muse, mutect2, varscan2
- DENND4B | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs781435616, COSV63409850; called by muse, varscan2
- DNAH11 | c.4474C>A p.L1492I | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100178471, COSV60962215; called by muse, mutect2, varscan2
- DNAH9 | c.13069A>G p.T4357A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52356033; called by muse, mutect2, varscan2
- DPP10 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1055873408, COSV59686211; called by muse, mutect2, varscan2
- DSEL | c.3529dup p.Y1177Lfs*5 | Frame Shift Ins (INS) | VAF 26/101 reads (26%) | catalogued as rs764875790; called by mutect2, pindel, varscan2
- EFNA4 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV99664892; called by muse, mutect2, varscan2
- GABRR1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765790320, COSV65620572; called by muse, mutect2, varscan2
- GUCY1A2 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs759653669, COSV56485046, COSV56503058; called by muse, mutect2, varscan2
- HELZ2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1335466059, COSV64409892; called by muse, mutect2
- HSPBAP1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748268421, COSV60242728; called by muse, mutect2, varscan2
- IL31RA | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV51681363; called by muse, mutect2, varscan2
- IRS4 | c.3163T>A p.C1055S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.097); catalogued as COSV64534348; called by muse, mutect2, varscan2
- ITGB6 | c.2073A>T p.K691N | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV51795530; called by muse, mutect2
- ITIH5 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 196/425 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.55); catalogued as rs762195658, COSV56898350; called by muse, mutect2, varscan2
- IVNS1ABP | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); catalogued as COSV100832663, COSV62251352; called by muse, mutect2, varscan2
- KATNAL2 | c.1427C>T p.A476V (on ENST00000356157 / NM_001353899.1; = p.A404V on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV99796300; called by muse, mutect2, varscan2
- KIF19 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs534622184, COSV63429724; called by muse, mutect2, varscan2
- KLHDC2 | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV53586958, COSV53587566; called by muse, mutect2, varscan2
- LNP1 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV67346890; called by muse, mutect2, varscan2
- LYPD4 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs782770551, COSV58027988; called by muse, mutect2, varscan2
- MAP2K7 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67608629; called by muse, varscan2
- MCPH1 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV60915100; called by muse, mutect2, varscan2
- MTMR6 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV67808676; called by muse, mutect2, varscan2
- MYRF | c.2510C>T p.T837M (on ENST00000278836 / NM_001127392.3; = p.T802M on NM_013279.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs200193085, COSV53890276; called by muse, mutect2, varscan2
- NAALAD2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs761176623, COSV58958461; called by muse, mutect2, varscan2
- NKAPD1 | c.504dup p.Q169Tfs*18 (on ENST00000280352 / NM_001082970.2; = p.Q170Tfs*18 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 35/178 reads (20%) | catalogued as rs757462125; called by pindel, varscan2
- OR7C2 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV50181022; called by muse, mutect2, varscan2
- PCDHA11 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 105/244 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs374687707, COSV56514685; called by muse, mutect2, varscan2
- PCDHA5 | c.1412G>T p.C471F | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.769); catalogued as COSV65353415; called by muse, mutect2, varscan2
- PCDHB16 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as rs781958254, COSV53358346, COSV99502819; called by muse, mutect2, varscan2
- PCDHGA3 | c.1948G>A p.G650S | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99535051; called by muse, mutect2
- PLA2G12A | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54669149, COSV54669573; called by muse, mutect2, varscan2
- PLCB4 | c.3505C>T p.R1169C (on ENST00000278655 / NM_182797.3; = p.P1181L on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.336); catalogued as rs1188180544, COSV53805537, COSV99597126; called by muse, mutect2, varscan2
- PLK1 | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV55622645; called by muse, mutect2, varscan2
- PREX1 | c.3577T>A p.L1193M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV64253188; called by muse, mutect2, varscan2
- PRR12 | c.1417C>T p.R473C (on ENST00000615927; = p.R1294C on NM_020719.3) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749458129, COSV69818044; called by muse, mutect2, varscan2
- PRTG | c.2854G>A p.A952T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV66838619; called by muse, mutect2, varscan2
- RBSN | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 13/152 reads (9%) | catalogued as COSV53793724; called by muse, mutect2
- RUNX1T1 | c.1462C>T p.R488C (on ENST00000265814 / NM_001198628.1; = p.R461C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs770002524, COSV56137763, COSV56148522; called by muse, mutect2, varscan2
- RYR1 | c.14474G>A p.R4825H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193922875, CM064214, COSV62095170; called by muse, mutect2, varscan2
- SHANK3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1469528649, COSV53184617; called by muse, mutect2, varscan2
- SIPA1 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs371556373; called by muse, mutect2, varscan2
- SLC2A7 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs779216554, COSV68901326; called by muse, mutect2, varscan2
- SYNE1 | c.22904C>T p.A7635V (on ENST00000367255 / NM_182961.4; = p.A7564V on NM_033071.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs555792275, COSV54926865; called by muse, mutect2, varscan2
- SYNE1 | c.10994T>C p.I3665T (on ENST00000367255 / NM_182961.4; = p.I3650T on NM_033071.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99559143; called by muse, mutect2, varscan2
- SYNE1 | c.7763G>T p.G2588V (on ENST00000367255 / NM_182961.4; = p.G2595V on NM_033071.3) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99559147; called by muse, mutect2, varscan2
- SYT8 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs190754396, COSV53288822, COSV53290055; called by muse, mutect2, varscan2
- THSD7A | c.1208G>A p.C403Y | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70266642; called by muse, mutect2, varscan2
- TRERF1 | c.2753C>A p.S918Y | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61673544; called by muse, mutect2, varscan2
- TRPC4 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1287965364, COSV58993391; called by muse, mutect2, varscan2
- TRPC7 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1397312641, COSV61454306; called by muse, mutect2, varscan2
- TTN | c.7711G>T p.E2571* (on ENST00000591111; = p.E2525* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 53/183 reads (29%) | catalogued as COSV60136909; called by muse, mutect2, varscan2
- WHAMM | c.1529A>C p.H510P | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54497180; called by muse, mutect2, varscan2
- ZNF638 | c.2633A>G p.N878S | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.192); catalogued as COSV52489628; called by muse, mutect2, varscan2
- ZNF668 | c.1546T>C p.F516L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV56215700; called by muse, mutect2, varscan2
- ZNF800 | c.670T>C p.S224P | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV99757812; called by muse, mutect2
- ZRANB2 | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV54672561; called by muse, mutect2, varscan2
- AKR1C8P | c.288A>T p.E96D | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CCDC183 | c.170_185del p.Q57Pfs*43 | Frame Shift Del (DEL) | VAF 24/47 reads (51%) | called by mutect2, pindel, varscan2
- IFIH1 | c.1412_1413del p.L471Qfs*32 | Frame Shift Del (DEL) | VAF 38/209 reads (18%) | called by mutect2, pindel, varscan2
- RBM12 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RHOBTB1 | c.597_598dup p.F200Cfs*10 | Frame Shift Ins (INS) | VAF 32/71 reads (45%) | called by mutect2, pindel, varscan2
- TFPT | c.53del p.F18Sfs*60 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- ABCC12 | c.2184G>A p.E728= | Silent (SNP) | VAF 11/246 reads (4%) | called by muse, mutect2
- BRINP1 | c.1515C>T p.F505= | Silent (SNP) | VAF 56/92 reads (61%) | catalogued as COSV56303427; called by muse, mutect2, varscan2
- CAPN15 | c.1146C>T p.P382= | Silent (SNP) | VAF 46/81 reads (57%) | catalogued as rs945309775, COSV54837014; called by muse, mutect2, varscan2
- CBX6 | c.1206T>G p.A402= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV53321161; called by muse, mutect2, varscan2
- CCDC59 | c.570C>T p.F190= | Silent (SNP) | VAF 92/176 reads (52%) | catalogued as rs764541070, COSV56281065; called by muse, mutect2, varscan2
- CDK5R2 | c.228G>A p.K76= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100225877; called by muse, mutect2
- CNGB3 | c.582G>A p.K194= | Silent (SNP) | VAF 46/384 reads (12%) | catalogued as COSV100181659; called by muse, mutect2, varscan2
- FASTKD5 | c.1791C>T p.N597= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV53906743; called by muse, mutect2, varscan2
- FAT2 | c.7929C>A p.V2643= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV55822245; called by muse, mutect2, varscan2
- FBXL7 | c.45C>A p.G15= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV61647900; called by muse, mutect2, varscan2
- FCGR3B | c.489A>T p.T163= | Silent (SNP) | VAF 192/444 reads (43%) | catalogued as COSV99670468; called by muse, mutect2, varscan2
- GLIS2 | c.1560G>A p.P520= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs759274279, COSV99267419; ClinVar: uncertain significance; called by muse, mutect2
- GRIK1 | c.615G>T p.L205= | Silent (SNP) | VAF 65/186 reads (35%) | catalogued as rs1168713083, COSV100516383; called by muse, mutect2, varscan2
- IGDCC4 | c.165A>T p.L55= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV61537614; called by muse, mutect2, varscan2
- IRS4 | c.765G>T p.R255= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs756750215, COSV64534354; called by muse, mutect2, varscan2
- LRP1B | c.6108C>T p.S2036= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV67236018, COSV67264256; called by muse, mutect2, varscan2
- LRP1B | c.4908C>T p.N1636= | Silent (SNP) | VAF 33/196 reads (17%) | catalogued as rs368565366; called by muse, mutect2, varscan2
- NCKAP5 | c.4338A>G p.E1446= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV58452012; called by muse, mutect2, varscan2
- PLXNA1 | c.1788C>T p.V596= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV52527990; called by muse, mutect2, varscan2
- PTPRT | c.2436C>T p.S812= | Silent (SNP) | VAF 95/188 reads (51%) | catalogued as rs145661499, COSV61962074, COSV61986179; called by muse, mutect2, varscan2
- RIF1 | c.1230C>T p.P410= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV54618781; called by muse, mutect2, varscan2
- SCUBE2 | c.321C>G p.G107= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV100496533; called by muse, mutect2, varscan2
- SORCS1 | c.3189G>A p.T1063= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs762368328, COSV53875901, COSV99550211; called by muse, mutect2, varscan2
- ST6GAL1 | c.1095G>A p.T365= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs750161610, COSV51469679; called by mutect2, varscan2
- SUPT6H | c.3240C>T p.A1080= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs200547240, COSV58928396; called by muse, mutect2, varscan2
- SYT17 | c.318G>A p.T106= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV62546756; called by muse, mutect2, varscan2
- TECTA | c.4302C>T p.Y1434= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs767937741, COSV50726092; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1080A>G p.V360= | Silent (SNP) | VAF 59/140 reads (42%) | catalogued as COSV54870120; called by muse, mutect2, varscan2
- AC013477.1 | c.*3dup | 3'UTR (INS) | VAF 122/353 reads (35%) | called by mutect2, pindel, varscan2
- AL132655.6 | chr20:58840415 C>T | 5'Flank (SNP) | VAF 45/93 reads (48%) | catalogued as rs373276011; called by muse, mutect2, varscan2
- C7orf66 | n.167C>A | RNA (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- FAM155A | c.*1C>T | 3'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as rs1245819704, COSV65566527; called by muse, mutect2, varscan2
- MTUS1 | c.2624-12777G>T | Intron (SNP) | VAF 33/60 reads (55%) | catalogued as COSV50562686; called by muse, mutect2, varscan2
- NRG1 | c.502+31419G>A | Intron (SNP) | VAF 165/271 reads (61%) | catalogued as rs550578958, COSV55162087; called by muse, mutect2, varscan2
